Somatic mutation profile of tumor specimen TCGA-24-2024-01A (aliquot TCGA-24-2024-01A-02W-0722-08) from TCGA case TCGA-24-2024, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.5 years (26,476 days).
Specimen TCGA-24-2024-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf0ea1e6-f30b-4632-9685-ecf5de1cdf41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2024-11A (Solid Tissue Normal), aliquot TCGA-24-2024-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ef7cdf9-9518-429e-985b-eb3698e7fc14

The open-access MAF lists 105 somatic variants for this specimen: 83 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 20, Nonsense Mutation 8, Frame Shift Del 4, Translation Start Site 2, Intron 2, Frame Shift Ins 2, Splice Site 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4286A>G p.Q1429R | Missense Mutation (SNP) | VAF 26/29 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1554085710, COSV57366932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 33/38 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3274C>T p.Q1092* (on ENST00000404938 / NM_001163941.2; = p.Q647* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 20/258 reads (8%) | catalogued as rs1201328024, COSV99327751, COSV99329115; called by muse, mutect2
- ABHD16A | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs750129081, COSV101013308; called by muse, mutect2
- ACLY | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs369798437; called by muse, mutect2
- AFP | c.644A>T p.E215V | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV99890238; called by muse, mutect2, varscan2
- AP002748.5 | c.1732G>C p.V578L | Missense Mutation (SNP) | VAF 125/273 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.741); catalogued as COSV59150754; called by muse, mutect2, varscan2
- AP2A1 | c.309C>G p.N103K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62820082; called by muse, mutect2, varscan2
- APBB3 | c.723T>A p.S241R (on ENST00000357560 / NM_133173.2; = p.S248R on NM_006051.3) | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV60052793; called by muse, mutect2, varscan2
- ARHGAP35 | c.2954C>G p.S985* | Nonsense Mutation (SNP) | VAF 27/32 reads (84%) | catalogued as COSV68334138; called by muse, mutect2, varscan2
- ATR | c.2824C>T p.H942Y | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100638448; called by muse, mutect2, varscan2
- BSN | c.10772G>A p.R3591H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs1017713426, COSV56524261; called by muse, mutect2, varscan2
- BTG2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV51857156; called by muse, mutect2, varscan2
- BTG2 | c.4A>T p.S2C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.237); catalogued as COSV99305890; called by muse, mutect2, varscan2
- CAGE1 | c.1366C>T p.Q456* (on ENST00000512086; = p.Q320* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV57080225; called by muse, mutect2, varscan2
- CHST8 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52861657; called by muse, mutect2, varscan2
- CIP2A | c.1589G>C p.R530T | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as COSV55418397, COSV55420277; called by muse, mutect2, varscan2
- COL3A1 | c.4220A>G p.K1407R | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV58593962; called by muse, varscan2
- COL6A2 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.703); catalogued as rs377376395, COSV56012296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL3 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100024659, COSV52368257; called by muse, mutect2, varscan2
- DCTN6 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1261148142, COSV55318306; called by muse, mutect2, varscan2
- DDX27 | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 6/148 reads (4%) | catalogued as COSV100872512; called by muse, mutect2
- DENND4C | c.3711T>G p.I1237M (on ENST00000434457 / NM_001330640.2; = p.I1188M on NM_017925.7) | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV63009447; called by muse, mutect2, varscan2
- DPP4 | c.928A>G p.R310G | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs375183248; called by muse, mutect2, varscan2
- FANCM | c.4997G>T p.R1666I | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57504471; called by muse, mutect2, varscan2
- FETUB | c.246C>G p.F82L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV54006657; called by muse, mutect2, varscan2
- GOLGB1 | c.7835C>T p.S2612F | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV61468996; called by muse, mutect2, varscan2
- GPR82 | c.330A>C p.L110F | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56887986; called by muse, mutect2, varscan2
- GRB2 | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV57306295; called by muse, varscan2
- HK1 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV53863474; called by muse, mutect2, varscan2
- HMGCS2 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | catalogued as COSV65568800; called by muse, mutect2, varscan2
- IRF3 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55864192; called by muse, mutect2, varscan2
- IRS1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs866580419, COSV59335281; called by muse, mutect2
- MAEA | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV53264072; called by muse, mutect2
- MAP3K12 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57234879; called by muse, mutect2, varscan2
- MCC | c.86A>T p.K29M | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs1310035865, COSV56733350; called by muse, mutect2, varscan2
- MDN1 | c.15013C>T p.Q5005* | Nonsense Mutation (SNP) | VAF 79/209 reads (38%) | catalogued as COSV65527131; called by muse, mutect2, varscan2
- MFSD8 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56552295; called by muse, mutect2, varscan2
- MLLT6 | c.1228_1230del p.S410del | In Frame Del (DEL) | VAF 12/25 reads (48%) | catalogued as rs1475042267; called by mutect2, pindel, varscan2
- MMP9 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748513980, COSV63433863; called by muse, mutect2, varscan2
- MRTFB | c.1734G>C p.E578D | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as COSV57960181; called by muse, mutect2, varscan2
- MTMR9 | c.1373G>T p.W458L | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99644472; called by muse, mutect2
- MUC16 | c.4152G>T p.W1384C | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV67481857; called by muse, mutect2, varscan2
- MYO3B | c.3145C>G p.H1049D | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58712000; called by muse, mutect2, varscan2
- NCAM2 | c.1846C>A p.Q616K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53093277; called by muse, mutect2, varscan2
- NEK3 | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV51618489; called by muse, mutect2, varscan2
- NELL1 | c.1304T>A p.I435N | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54302942; called by muse, mutect2, varscan2
- NOTCH4 | c.5425C>A p.Q1809K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV66682805; called by muse, mutect2, varscan2
- NR1I2 | c.652dup p.E218Gfs*28 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | catalogued as rs1559790718; called by pindel, varscan2
- OR10G4 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV57978523; called by muse, mutect2, varscan2
- OR1N2 | c.677G>T p.W226L | Missense Mutation (SNP) | VAF 188/244 reads (77%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101031376, COSV65460990; called by muse, mutect2, varscan2
- PCDHB11 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs553664559, COSV53381840; called by muse, mutect2, varscan2
- PCDHB11 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV100697227; called by muse, mutect2
- PCDHGA10 | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV54001224; called by muse, mutect2, varscan2
- PDGFRA | c.1292A>G p.Q431R | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV57271577; called by muse, mutect2, varscan2
- RB1CC1 | c.4231G>T p.G1411* | Nonsense Mutation (SNP) | VAF 68/131 reads (52%) | catalogued as COSV50263117; called by muse, mutect2, varscan2
- RHOT1 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV100447489; called by muse, mutect2, varscan2
- SALL4 | c.2527G>A p.G843S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99409752; called by muse, mutect2, varscan2
- SELE | c.1541C>G p.T514S | Missense Mutation (SNP) | VAF 61/96 reads (64%) | SIFT tolerated (0.38); PolyPhen benign (0.249); catalogued as COSV60976997; called by muse, mutect2, varscan2
- SERPINE3 | c.602G>T p.R201I | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV68545707; called by muse, mutect2, varscan2
- SF3A1 | c.2131G>T p.V711L | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.66); catalogued as COSV53170496; called by muse, mutect2, varscan2
- SIGLEC12 | c.1258C>G p.L420V (on ENST00000291707 / NM_053003.4; = p.L302V on NM_033329.2) | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52463673; called by muse, mutect2, varscan2
- SLC29A2 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60803303, COSV60803918; called by muse, mutect2, varscan2
- SLC2A3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV50005617; called by muse, mutect2, varscan2
- SLC4A9 | c.1394C>G p.P465R (on ENST00000507527 / NM_001258428.2; = p.P441R on NM_031467.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50202915; called by muse, mutect2, varscan2
- SORL1 | c.1864G>T p.G622* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | catalogued as COSV52757456, COSV52759407; called by muse, mutect2, varscan2
- ST8SIA1 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 103/170 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.185); catalogued as COSV53957423; called by muse, mutect2, varscan2
- TACR3 | c.1104G>C p.K368N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59201193, COSV59206050; called by muse, mutect2, varscan2
- TAOK3 | c.192+1G>A p.X64_splice | Splice Site (SNP) | VAF 10/113 reads (9%) | catalogued as COSV100700385; called by muse, mutect2
- TBCA | c.194C>G p.P65R | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60539614; called by muse, mutect2, varscan2
- TGFB2 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 242/984 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100860356; called by muse, mutect2, varscan2
- TMOD2 | c.838del p.E280Kfs*5 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as COSV51045926; called by mutect2, pindel, varscan2
- UNC13B | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 57/76 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV65937209; called by muse, mutect2, varscan2
- WNT6 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as COSV52110783; called by muse, varscan2
- XIRP2 | c.2948A>T p.Q983L (on ENST00000628543; = p.Q1158L on NM_152381.6) | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV54722211; called by muse, mutect2, varscan2
- ZNF654 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV58806851; called by muse, mutect2, varscan2
- ABCB6 | c.2072_2094del p.A691Gfs*9 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel
- BAAT | c.668dup p.V224Gfs*35 | Frame Shift Ins (INS) | VAF 22/36 reads (61%) | called by mutect2, pindel, varscan2
- ERCC6 | c.3103del p.H1035Ifs*2 | Frame Shift Del (DEL) | VAF 151/506 reads (30%) | called by mutect2, pindel, varscan2
- ETV5 | c.4_16del p.D2Ifs*22 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- FAT1 | c.10802C>T p.A3601V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- RELN | c.1542_1554+31del p.X514_splice | Splice Site (DEL) | VAF 42/210 reads (20%) | called by mutect2, pindel
- SPAM1 | c.157_165del p.W53_A55del | In Frame Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- CCDC159 | c.432C>T p.F144= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1235395276, COSV52261606; called by muse, mutect2, varscan2
- CPED1 | c.1257A>T p.I419= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV60008871; called by muse, mutect2, varscan2
- CSMD3 | c.9513C>A p.I3171= (on ENST00000297405 / NM_001363185.1; = p.I3002= on NM_052900.3) | Silent (SNP) | VAF 109/293 reads (37%) | catalogued as COSV52266436; called by muse, mutect2, varscan2
- GPATCH2 | c.1104C>A p.P368= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100861812; called by muse, mutect2, varscan2
- GSPT2 | c.48C>T p.D16= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV61214784; called by muse, mutect2, varscan2
- IGHV2-26 | c.300C>A p.V100= | Silent (SNP) | VAF 162/399 reads (41%) | called by muse, mutect2
- ITIH1 | c.237C>A p.A79= | Silent (SNP) | VAF 31/43 reads (72%) | catalogued as COSV56257360; called by muse, mutect2, varscan2
- MC3R | c.198C>T p.N66= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs961326205, COSV54763540; called by muse, mutect2, varscan2
- ODF3 | c.126G>A p.T42= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs374039790; called by muse, mutect2, varscan2
- OGFOD3 | c.249G>A p.G83= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV57342469; called by muse, mutect2, varscan2
- OR4K13 | c.864A>G p.T288= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV59860309; called by muse, mutect2, varscan2
- PARP1 | c.1668C>T p.T556= | Silent (SNP) | VAF 72/224 reads (32%) | catalogued as rs1416206852, COSV64691607; called by muse, mutect2, varscan2
- PDE4DIP | c.4167G>T p.S1389= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV57697979, COSV57717926; called by muse, mutect2, varscan2
- POLB | c.27G>A p.E9= | Silent (SNP) | VAF 97/248 reads (39%) | catalogued as COSV99613283; called by muse, mutect2, varscan2
- POLR1A | c.5031C>T p.S1677= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV55693397, COSV55697202; called by muse, mutect2, varscan2
- SGK3 | c.1029T>C p.D343= | Silent (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- TAS2R40 | c.543G>A p.T181= | Silent (SNP) | VAF 123/249 reads (49%) | catalogued as rs755951183, COSV68818087; called by muse, mutect2, varscan2
- TRIML2 | c.1074G>A p.L358= | Silent (SNP) | VAF 76/209 reads (36%) | catalogued as rs1306747187, COSV58717864; called by mutect2, varscan2
- TUBGCP6 | c.3336C>T p.N1112= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as rs368660390; ClinVar: likely benign; called by muse, mutect2, varscan2
- XPOT | c.2325G>C p.V775= | Silent (SNP) | VAF 154/367 reads (42%) | catalogued as COSV60347170; called by muse, mutect2, varscan2
- MAP3K19 | c.3222+371C>G | Intron (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100208980; called by muse, mutect2, varscan2
- NFASC | c.2470+2078C>T | Intron (SNP) | VAF 31/84 reads (37%) | catalogued as COSV58374157; called by muse, mutect2, varscan2
